Somatic mutation profile of tumor specimen TCGA-AC-A8OP-01A (aliquot TCGA-AC-A8OP-01A-11D-A36J-09) from TCGA case TCGA-AC-A8OP, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 72.7 years (26,550 days).
Specimen TCGA-AC-A8OP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f9347ff-4a82-413d-8ac4-adad8b80c8ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A8OP-10A (Blood Derived Normal), aliquot TCGA-AC-A8OP-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8d813dc-51db-4344-a3f0-1e243cd3f490

The open-access MAF lists 153 somatic variants for this specimen: 109 protein-altering or splice-affecting, 43 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 43, Nonsense Mutation 11, Frame Shift Del 4, Splice Site 3, Frame Shift Ins 2, Splice Region 1, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAI1 | c.3398C>G p.S1133* | Nonsense Mutation (SNP) | VAF 39/69 reads (57%) | catalogued as rs750335388, COSV99884357; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.7104+2T>C p.X2368_splice (on ENST00000272895 / NM_173076.3; = p.X2050_splice on NM_015657.3) | Splice Site (SNP) | VAF 17/147 reads (12%) | catalogued as COSV99790617; called by muse, mutect2, varscan2
- ABCA8 | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV99286204; called by muse, mutect2, varscan2
- ACLY | c.2798A>G p.D933G | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); catalogued as COSV100709751; called by muse, mutect2, varscan2
- ACOT9 | c.86C>G p.P29R | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.014); catalogued as COSV100321338; called by muse, mutect2, varscan2
- ADAMTS9 | c.4837G>A p.E1613K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as rs749861523, COSV55791840; called by muse, mutect2, varscan2
- ADCY5 | c.2165G>A p.R722H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as rs1553725039, COSV59198464; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AL162417.1 | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 11/99 reads (11%) | catalogued as rs149262357; called by muse, mutect2, varscan2
- ALG14 | c.513C>A p.Y171* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100930876; called by muse, mutect2, varscan2
- ANKRD20A1 | c.1922C>A p.S641Y | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs556460736; called by muse, mutect2, varscan2
- ANKRD26 | c.3900G>T p.K1300N | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.49); catalogued as COSV101063276, COSV65773700; called by muse, mutect2, varscan2
- AR | c.1082G>A p.S361N | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.015); catalogued as COSV101018616; called by muse, mutect2, varscan2
- ASAH2 | c.179G>C p.G60A | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.003); catalogued as rs142364715, COSV100269983, COSV61483862; called by muse, mutect2, varscan2
- ATP2B3 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.044); catalogued as rs148126611, COSV99684916; called by muse, mutect2, varscan2
- ATP7A | c.4179G>T p.M1393I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100431103; called by muse, mutect2, varscan2
- ATP7A | c.4180G>C p.A1394P | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100431107; called by muse, mutect2, varscan2
- CAMK2G | c.1674G>C p.Q558H (on ENST00000423381 / NM_001367518.1; = p.Q495H on NM_001222.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV99989980; called by muse, varscan2
- CASP8AP2 | c.1201C>T p.H401Y | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV99387170; called by muse, mutect2, varscan2
- CDCP1 | c.2082-1G>T p.X694_splice | Splice Site (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99944119; called by muse, mutect2
- CDHR1 | c.974T>C p.M325T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV100259060; called by muse, mutect2, varscan2
- CDK1 | c.376C>A p.H126N | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100358861; called by muse, mutect2, varscan2
- CGN | c.2770G>C p.A924P | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.625); catalogued as rs748587096, COSV99642466; called by muse, mutect2, varscan2
- CHEK2 | c.956T>A p.I319N (on ENST00000382580 / NM_001005735.2; = p.I276N on NM_007194.4) | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100101953, COSV60423273; called by muse, mutect2, varscan2
- CLEC2B | c.167G>T p.W56L | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99947006; called by muse, mutect2, varscan2
- CLINT1 | c.1467A>C p.L489F | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99754283; called by muse, mutect2, varscan2
- COL4A5 | c.2129G>A p.G710E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100088214; called by muse, mutect2, varscan2
- CROCC | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1024085663, COSV100978288; called by muse, mutect2, varscan2
- DCHS1 | c.1258G>A p.V420I | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs761187405, COSV55036733; called by mutect2, varscan2
- DDX46 | c.1570A>T p.T524S | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as COSV62800215; called by muse, mutect2, varscan2
- DIDO1 | c.6628G>C p.D2210H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); catalogued as COSV99826253; called by muse, mutect2, varscan2
- DPEP2 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.132); catalogued as COSV99263161; called by muse, mutect2, varscan2
- EFCAB6 | c.2753C>A p.P918H | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV99413692; called by muse, mutect2, varscan2
- ELAPOR1 | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.162); catalogued as COSV100884721; called by mutect2, varscan2
- FAM200A | c.759T>G p.I253M | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.082); catalogued as COSV101282733; called by muse, mutect2, varscan2
- FAM98C | c.592C>G p.L198V | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.298); catalogued as COSV99385038; called by muse, mutect2, varscan2
- FBN3 | c.8251C>T p.R2751C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); catalogued as rs376621511; called by muse, mutect2, varscan2
- FN3K | c.513C>A p.H171Q | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100333320; called by muse, mutect2, varscan2
- FNDC4 | c.448A>G p.S150G | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1161882162, COSV99253938; called by muse, mutect2, varscan2
- GABPB2 | c.1-1G>T p.X1_splice | Splice Site (SNP) | VAF 6/86 reads (7%) | catalogued as COSV100927251; called by muse, mutect2
- GATA3 | c.990dup p.N331Efs*21 | Frame Shift Ins (INS) | VAF 16/59 reads (27%) | catalogued as COSV60516089, COSV60517561; called by mutect2, pindel, varscan2
- GSE1 | c.3220G>A p.A1074T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.236); catalogued as rs376390313, COSV53670926; called by muse, mutect2, varscan2
- H1-8 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs767430899, COSV100180489; called by muse, mutect2, varscan2
- H2AC14 | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100297629, COSV60797902; called by muse, mutect2, varscan2
- HAP1 | c.1463C>A p.A488D (on ENST00000310778 / NM_001367460.1; = p.A436D on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV100169821; called by muse, mutect2, varscan2
- IGHA2 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.329); catalogued as rs377678733; called by muse, mutect2, varscan2
- IGLV2-14 | c.345C>A p.S115R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.286); catalogued as rs565111514; called by muse, mutect2, varscan2
- KAT7 | c.1607G>C p.G536A | Missense Mutation (SNP) | VAF 36/345 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as COSV99371849; called by muse, mutect2
- KLHL1 | c.603G>C p.K201N | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); catalogued as COSV64775536; called by muse, mutect2, varscan2
- KMT2C | c.5029C>T p.Q1677* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | catalogued as COSV100073343; called by muse, mutect2
- LAX1 | c.259C>T p.Q87* | Nonsense Mutation (SNP) | VAF 18/179 reads (10%) | catalogued as COSV100920064; called by muse, mutect2, varscan2
- MAS1 | c.658G>T p.A220S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.05); catalogued as COSV99396931; called by muse, mutect2, varscan2
- MGAM | c.5471C>G p.S1824C | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as COSV101527553, COSV101527568; called by muse, mutect2, varscan2
- MINDY1 | c.1378C>A p.P460T | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV100385478; called by muse, varscan2
- MIPOL1 | c.1015C>T p.L339F | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100539172; called by muse, mutect2, varscan2
- MMP8 | c.1099A>C p.N367H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV99368550; called by muse, mutect2, varscan2
- MYO18A | c.3789C>G p.I1263M | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as COSV100572106, COSV100572409; called by muse, mutect2, varscan2
- MYOT | c.325A>C p.S109R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.119); catalogued as COSV99524978; called by muse, mutect2, varscan2
- NAPA | c.791A>T p.K264M | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99645810; called by muse, mutect2, varscan2
- NCAPG2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100690687; called by muse, mutect2, varscan2
- NCOR1 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV99250594; called by muse, mutect2, varscan2
- NKX3-2 | c.706C>A p.R236S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101219926; called by muse, mutect2, varscan2
- NLGN4X | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99322453; called by muse, mutect2, varscan2
- NLRP7 | c.2897A>T p.N966I (on ENST00000340844 / NM_206828.3; = p.N995I on NM_139176.3) | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV100052913; called by muse, mutect2, varscan2
- NR0B1 | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as rs766165592, CD961749, COSV100973545; called by muse, mutect2, varscan2
- OR5H2 | c.284G>T p.R95M | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV62350560, COSV62351802; called by muse, varscan2
- OR5T1 | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100479105; called by muse, mutect2, varscan2
- OTOF | c.173G>A p.R58K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs201067363, COSV99718092; called by muse, mutect2, varscan2
- PCDHGA7 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.035); catalogued as rs763555331, COSV53903729, COSV53920818; called by muse, mutect2, varscan2
- PLA2G4A | c.841A>G p.K281E | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV100820598; called by muse, mutect2, varscan2
- PLCH2 | c.298A>C p.S100R | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV99616596; called by muse, mutect2, varscan2
- PLEKHG6 | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); catalogued as rs761204546, COSV99164402; called by muse, mutect2, varscan2
- RAI1 | c.2807C>G p.S936* | Nonsense Mutation (SNP) | VAF 89/128 reads (70%) | catalogued as COSV99884354; called by muse, mutect2, varscan2
- RAI1 | c.4181C>A p.S1394Y | Missense Mutation (SNP) | VAF 83/131 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as COSV99884363; called by muse, mutect2, varscan2
- RAI2 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 21/55 reads (38%) | catalogued as COSV100518398; called by muse, mutect2, varscan2
- RGS9 | c.1056G>C p.E352D | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99287595; called by muse, mutect2
- RIMBP2 | c.1009G>T p.D337Y | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99899801; called by muse, mutect2, varscan2
- RPH3A | c.290G>A p.R97H (on ENST00000389385 / NM_001143854.2; = p.R93H on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.541); catalogued as rs199724124, COSV66992806; called by muse, mutect2, varscan2
- RSPH10B | c.611A>C p.Y204S | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100521336; called by muse, mutect2
- RUNX1T1 | c.1763C>T p.P588L (on ENST00000265814 / NM_001198628.1; = p.P561L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as rs147343453, COSV56137322; called by muse, mutect2, varscan2
- SBF2 | c.1536C>G p.N512K | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as COSV56306628, COSV99814724; called by muse, mutect2, varscan2
- SDR16C5 | c.587C>A p.A196E | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1174307218, COSV100374043; called by muse, mutect2
- SEMA3C | c.280T>A p.S94T | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.1); catalogued as COSV99543234; called by muse, mutect2, varscan2
- SGSM1 | c.2188G>T p.V730L (on ENST00000400359 / NM_001039948.4; = p.V669L on NM_133454.3) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV100771875; called by muse, mutect2
- SLIT1 | c.144C>A p.H48Q | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99821746; called by muse, mutect2, varscan2
- SMNDC1 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); catalogued as COSV100852166; called by muse, mutect2, varscan2
- SOX4 | c.1367A>T p.E456V | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99782075; called by muse, mutect2, varscan2
- SPACA1 | c.307G>T p.G103C | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52761820; called by muse, mutect2, varscan2
- SPHKAP | c.1820G>C p.S607T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.084); catalogued as COSV100764234; called by muse, mutect2, varscan2
- SPTBN4 | c.6155A>C p.Q2052P | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100151293; called by muse, mutect2, varscan2
- SSR4 | c.498T>G p.S166R | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV99381442; called by muse, mutect2, varscan2
- SVIL | c.3195G>T p.Q1065H (on ENST00000355867 / NM_021738.3; = p.Q639H on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.336); catalogued as COSV100881358; called by muse, mutect2, varscan2
- TASP1 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV100534675; called by muse, varscan2
- TEX15 | c.7151C>T p.T2384M (on ENST00000256246; = p.T2767M on NM_001350162.2) | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as rs759813914, COSV56342929; called by muse, mutect2, varscan2
- TRAPPC9 | c.3278C>T p.A1093V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.039); catalogued as rs750167029; ClinVar: uncertain significance; called by mutect2, varscan2
- TRPM1 | c.1439T>C p.L480P | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99856137; called by muse, mutect2, varscan2
- TSPOAP1 | c.4651C>T p.R1551C | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs748011478, COSV99271538; called by muse, mutect2
- TTN | c.58174G>T p.E19392* (on ENST00000591111; = p.E11968* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100618639, COSV60362332; called by muse, mutect2, varscan2
- UGT1A9 | c.283C>G p.H95D | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100692966; called by muse, mutect2, varscan2
- XYLT1 | c.2243C>T p.A748V | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.953); catalogued as COSV54500598; called by muse, mutect2, varscan2
- ZNF292 | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as COSV100370585; called by muse, mutect2, varscan2
- ZNF420 | c.1708C>T p.R570C | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.865); catalogued as rs765172465, COSV58493901, COSV58495635; called by mutect2, varscan2
- ZNF569 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as rs774136758, COSV100386526; called by muse, mutect2, varscan2
- ZSCAN29 | c.1846C>T p.Q616* | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as COSV101212217; called by muse, mutect2, varscan2
- ARID1A | c.2182_2191del p.P728Afs*11 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel
- GJA10 | c.712del p.I238Lfs*2 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- KLC4 | c.1048_1072del p.Q350Afs*21 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel
- NHP2 | c.230+2dup | Splice Region (INS) | VAF 22/102 reads (22%) | called by mutect2, pindel, varscan2
- PVALB | c.86dup p.F30Vfs*14 | Frame Shift Ins (INS) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- SYCP1 | c.916_917del p.Q306Efs*2 | Frame Shift Del (DEL) | VAF 6/57 reads (11%) | called by mutect2, varscan2
- ABCA13 | c.11034G>A p.A3678= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs775259214, COSV101447002, COSV71285327; called by muse, mutect2, varscan2
- ADH7 | c.687T>G p.S229= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV99265323; called by muse, mutect2, varscan2
- ATP11B | c.186G>A p.Q62= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as rs1427687330, COSV100017881; called by muse, mutect2, varscan2
- ATXN2L | c.2473C>T p.L825= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs772963655, COSV100294610; called by muse, mutect2, varscan2
- AUTS2 | c.3222C>G p.P1074= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV100718075; called by muse, mutect2, varscan2
- BCLAF3 | c.2037T>A p.R679= (on ENST00000379682 / NM_001367774.1; = p.R650= on NM_198279.3) | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV100503333; called by muse, mutect2, varscan2
- CAPN12 | c.462G>A p.V154= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs758957246, COSV100185349; called by muse, mutect2, varscan2
- CGB7 | c.111T>C p.A37= | Silent (SNP) | VAF 33/197 reads (17%) | catalogued as COSV100655071; called by muse, mutect2, varscan2
- COL20A1 | c.2073C>T p.H691= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs1164295610, COSV100490792, COSV58924311; called by muse, mutect2, varscan2
- CPN2 | c.126C>T p.T42= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs150511099; called by muse, mutect2, varscan2
- DOHH | c.141C>T p.F47= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as rs371544653; called by muse, mutect2, varscan2
- EBF3 | c.1557C>T p.Y519= (on ENST00000355311 / NM_001375392.1; = p.Y510= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as rs147171591; called by muse, mutect2, varscan2
- GRK1 | c.538C>T p.L180= | Silent (SNP) | VAF 6/75 reads (8%) | catalogued as rs1336285099, COSV59551663; called by muse, mutect2
- HLA-G | c.639G>A p.V213= | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as COSV100827125; called by muse, mutect2, varscan2
- HSPA6 | c.954G>A p.P318= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as rs1214543911, COSV100554195; called by muse, mutect2, varscan2
- IL9R | c.423C>G p.P141= | Silent (SNP) | VAF 5/61 reads (8%) | catalogued as COSV99729939; called by muse, mutect2
- KCNB2 | c.177G>A p.T59= | Silent (SNP) | VAF 42/137 reads (31%) | catalogued as rs566076958, COSV73049681; called by muse, mutect2, varscan2
- MTMR4 | c.2121C>T p.T707= | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as rs748294907, COSV60200047; called by muse, mutect2
- MUC5B | c.8481G>A p.T2827= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs1293108994, COSV71595911; called by muse, varscan2
- MYO15A | c.10092C>A p.V3364= | Silent (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- MYO16 | c.3801C>T p.L1267= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as rs372764867; called by muse, mutect2, varscan2
- NLRP12 | c.1032C>T p.P344= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs776232316, COSV100145439; called by muse, mutect2, varscan2
- NOTCH3 | c.927G>A p.E309= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as COSV99657739; called by muse, mutect2, varscan2
- NRG1 | c.951C>T p.V317= (on ENST00000405005 / NM_013964.5; = p.V322= on NM_013956.5) | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV99828650; called by muse, varscan2
- OGDH | c.1629G>T p.L543= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV99759134; called by muse, mutect2, varscan2
- OR4C15 | c.153C>A p.S51= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100115796, COSV58951434; called by muse, mutect2, varscan2
- PCARE | c.1425G>A p.P475= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs755455124, COSV100527490; called by muse, mutect2, varscan2
- PCDHA13 | c.1293C>A p.G431= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV56523956; called by muse, mutect2, varscan2
- PPP2R1A | c.6G>T p.A2= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as COSV100436330; called by muse, mutect2, varscan2
- PRMT3 | c.927T>A p.I309= | Silent (SNP) | VAF 19/135 reads (14%) | catalogued as COSV100424000; called by muse, varscan2
- PRMT3 | c.978C>T p.I326= | Silent (SNP) | VAF 19/137 reads (14%) | catalogued as COSV100424002; called by muse, varscan2
- PTPRZ1 | c.2076C>A p.S692= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV101100342, COSV66440696; called by muse, mutect2, varscan2
- RBP3 | c.1215C>T p.A405= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs782291267; called by muse, mutect2, varscan2
- RELB | c.1287C>T p.G429= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as COSV99673004; called by muse, mutect2, varscan2
- RPS29 | c.88C>T p.L30= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs3211474, COSV99817939; called by muse, mutect2, varscan2
- SACS | c.11808G>T p.G3936= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV101207512; called by muse, mutect2, varscan2
- SH3RF1 | c.984C>G p.P328= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV99499181; called by muse, mutect2, varscan2
- SLC6A11 | c.276C>T p.Y92= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as rs376760918; called by muse, mutect2, varscan2
- UBR2 | c.924C>T p.V308= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as rs762803625, COSV100867469; called by muse, mutect2, varscan2
- WDR33 | c.1611A>G p.T537= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100460279; called by muse, mutect2, varscan2
- ZC3H12B | c.1584T>C p.I528= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV100161829; called by muse, mutect2, varscan2
- ZMIZ2 | c.279G>A p.A93= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs200981133; called by muse, mutect2, varscan2
- ZNF682 | c.276A>G p.Q92= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV100653296, COSV62066630; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500187 T>A | 5'Flank (SNP) | VAF 29/121 reads (24%) | catalogued as rs755533754; called by muse, mutect2, varscan2
